Somatic mutation profile of tumor specimen 0DPE9M from CCDI case PBCDNW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Mesenchymal chondrosarcoma; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Age at diagnosis: 16.9 years (6,179 days).
Specimen 0DPE9M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d860999b-be9d-4548-acf0-e7f04727be15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPE97 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fdd4ef7-a3ab-4f0e-af0f-83ca66e5aa18

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USP8 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs368365577, COSV56168598; called by muse, mutect2, varscan2
- XDH | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 129/322 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754254449, COSV101051925; called by muse, mutect2, varscan2
- CPNE6 | c.274T>A p.F92I | Missense Mutation (SNP) | VAF 181/409 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- HSD17B2 | c.993G>A p.A331= | Silent (SNP) | VAF 245/497 reads (49%) | catalogued as rs534097987, COSV52275791; called by muse, mutect2, varscan2
- NCK2 | c.753C>T p.Y251= | Silent (SNP) | VAF 93/230 reads (40%) | catalogued as rs1215871161, COSV51890145; called by muse, mutect2, varscan2
- AAR2 | c.*32C>T | 3'UTR (SNP) | VAF 87/178 reads (49%) | called by muse, mutect2, varscan2
- CNTN6 | c.2986+19G>T | Intron (SNP) | VAF 64/134 reads (48%) | catalogued as rs747977614; called by muse, mutect2, varscan2
